Somatic mutation profile of tumor specimen TCGA-44-2668-01A (aliquot TCGA-44-2668-01A-01D-A271-08) from TCGA case TCGA-44-2668, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.6 years (18,856 days).
Specimen TCGA-44-2668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42148863-8ba8-4fad-b30f-348f37ece4cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2668-10A (Blood Derived Normal), aliquot TCGA-44-2668-10A-01D-1489-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b20883e-ea60-4c63-8f61-acd6ed5a8125

The open-access MAF lists 376 somatic variants for this specimen: 284 protein-altering or splice-affecting, 88 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 88, Nonsense Mutation 23, Splice Site 11, Frame Shift Del 9, Splice Region 2, 5'UTR 1, 5'Flank 1, Intron 1, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INS-IGF2 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80356664, CM074280, CM074281, CM1314526, COSV51747478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2
- TGFBR2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893810, CM050761, CM140638, COSV55443375, COSV55461069, COSV99848566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | hotspot (GDC flag); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as rs376370716; called by muse, mutect2, varscan2
- ACER2 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61820950; called by muse, mutect2, varscan2
- ADAMTS20 | c.4640G>A p.C1547Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV67133587; called by muse, mutect2, varscan2
- ADAMTS4 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 22/205 reads (11%) | catalogued as COSV63488058; called by muse, mutect2, varscan2
- ADCY2 | c.982-1G>T p.X328_splice | Splice Site (SNP) | VAF 34/177 reads (19%) | catalogued as COSV57879098; called by muse, mutect2, varscan2
- ADGRA1 | c.1149C>A p.S383R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as COSV100811012; called by muse, mutect2, varscan2
- ADGRB3 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV65401825; called by muse, mutect2, varscan2
- ADGRE1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV51677006; called by muse, mutect2, varscan2
- AFF2 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60669144; called by mutect2, varscan2
- AHI1 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV55629204; called by muse, mutect2
- AKAP1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs756461688, COSV58470959; called by muse, mutect2, varscan2
- AMOT | c.2416A>T p.T806S (on ENST00000371959 / NM_001113490.1; = p.T397S on NM_133265.3) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV59064774; called by muse, mutect2, varscan2
- ANGEL1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1356414829, COSV51873956; called by muse, mutect2, varscan2
- ANGPT4 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67921955; called by muse, mutect2, varscan2
- ANK2 | c.9628A>G p.T3210A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV52168144; called by muse, mutect2, varscan2
- ANKFN1 | c.1624C>G p.H542D | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.169); catalogued as COSV59450694; called by muse, mutect2, varscan2
- ANKH | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52482285, COSV99414490; called by muse, mutect2, varscan2
- AQP10 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59246622; called by muse, mutect2, varscan2
- ASIC4 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61732282; called by muse, mutect2, varscan2
- ASXL3 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV52469738; called by muse, mutect2, varscan2
- ATP8A2 | c.3279G>T p.K1093N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54958704; called by muse, mutect2, varscan2
- BCHE | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV52258139; called by muse, mutect2, varscan2
- BEST4 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 39/286 reads (14%) | catalogued as rs138830699; called by muse, mutect2, varscan2
- BPIFB6 | c.97+1G>T p.X33_splice | Splice Site (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100848489; called by muse, mutect2, varscan2
- BTN2A1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201411917, COSV57004085; called by muse, mutect2, varscan2
- C1orf105 | c.418T>A p.Y140N | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62959489; called by muse, varscan2
- C4orf17 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.792); catalogued as COSV58512810; called by muse, mutect2, varscan2
- C9orf64 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV59032715; called by muse, mutect2, varscan2
- CACNA1H | c.6677del p.T2226Sfs*36 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV52352653; called by mutect2, pindel, varscan2
- CASP4 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67744530; called by muse, mutect2, varscan2
- CCDC28A | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs143442772; called by muse, mutect2, varscan2
- CCDC57 | c.719G>T p.R240M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV66433924, COSV66434564; called by muse, mutect2, varscan2
- CD200R1 | c.307G>T p.E103* (on ENST00000471858 / NM_170780.3; = p.E126* on NM_138806.4) | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV55601504; called by muse, mutect2, varscan2
- CDH10 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52584948; called by muse, mutect2, varscan2
- CDH6 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54071180, COSV54072095; called by muse, mutect2, varscan2
- CDH6 | c.1907T>A p.L636Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV54072103; called by muse, mutect2, varscan2
- CDH7 | c.2191C>A p.Q731K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59888138; called by muse, mutect2, varscan2
- CEP20 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as COSV55384481; called by muse, mutect2, varscan2
- CFI | c.1045-2A>T p.X349_splice | Splice Site (SNP) | VAF 30/189 reads (16%) | catalogued as COSV67098982; called by muse, mutect2
- CHD8 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.428); catalogued as COSV101303091; called by muse, mutect2, varscan2
- CHD9 | c.5581A>T p.R1861* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV54611874; called by muse, mutect2, varscan2
- CHRM3 | c.1592G>C p.W531S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55104940, COSV99697990; called by muse, mutect2, varscan2
- CHRM3 | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55108107, COSV99697992; called by muse, mutect2, varscan2
- CLRN2 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV72512587; called by muse, mutect2, varscan2
- CNTN3 | c.2944G>C p.D982H | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV55175046; called by muse, mutect2, varscan2
- CNTNAP2 | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.184); catalogued as COSV62201650; called by muse, mutect2, varscan2
- COBL | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.386); catalogued as COSV54348893; called by muse, mutect2, varscan2
- COG5 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51754667; called by muse, mutect2, varscan2
- COL22A1 | c.3914C>G p.P1305R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV100279666, COSV57342867; called by muse, mutect2, varscan2
- COL24A1 | c.2656del p.E886Kfs*50 | Frame Shift Del (DEL) | VAF 27/183 reads (15%) | catalogued as COSV65304056; called by mutect2, pindel, varscan2
- COL4A6 | c.2780G>T p.G927V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859421, COSV57869363; called by muse, mutect2, varscan2
- COL4A6 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57869376; called by muse, mutect2, varscan2
- COL6A3 | c.1631G>T p.R544L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780201464, COSV55094333; called by muse, mutect2
- CSMD3 | c.8710G>C p.G2904R (on ENST00000297405 / NM_001363185.1; = p.G2735R on NM_052900.3) | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52213938; called by muse, mutect2
- CSMD3 | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.761); catalogued as COSV52213955; called by muse, mutect2
- CSNK1D | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV58365102; called by muse, mutect2, varscan2
- CYP4F2 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV50001627; called by muse, mutect2, varscan2
- DCT | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV65469687; called by muse, mutect2, varscan2
- DDX11 | c.1955T>G p.V652G | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52506006, COSV52507585; called by muse, mutect2, varscan2
- DDX49 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); catalogued as rs749236961, COSV53231010; called by muse, mutect2
- DERL1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52365157; called by muse, mutect2, varscan2
- DHRSX | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 13/111 reads (12%) | catalogued as COSV58135095; called by muse, mutect2
- DHTKD1 | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53804398, COSV53806440; called by muse, mutect2, varscan2
- DHX32 | c.177A>T p.R59S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52941025; called by muse, mutect2, varscan2
- DLGAP2 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.147); catalogued as COSV70099886; called by muse, mutect2, varscan2
- DNAH1 | c.11593G>A p.D3865N | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV56235798; called by muse, mutect2, varscan2
- DNAH9 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201122944, COSV52356066; called by muse, mutect2
- DPP6 | c.2512T>A p.S838T (on ENST00000377770 / NM_001364500.2; = p.S776T on NM_001936.5) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.133); catalogued as COSV59622580; called by muse, varscan2
- DROSHA | c.854G>T p.R285I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV60777911; called by muse, mutect2, varscan2
- DUSP6 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54378990; called by muse, mutect2, varscan2
- DYDC2 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV55472654; called by muse, mutect2, varscan2
- EIF2D | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55114118; called by muse, mutect2, varscan2
- EPHA4 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56036407; called by muse, mutect2, varscan2
- EPHA6 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67577491; called by muse, mutect2, varscan2
- ERICH3 | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58603768; called by muse, mutect2, varscan2
- ERICH3 | c.1850G>C p.R617T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58609992, COSV58620417; called by muse, mutect2, varscan2
- ERICH6 | c.1806G>C p.K602N | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55799476, COSV55801319; called by muse, mutect2, varscan2
- ESD | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66340464, COSV66340808; called by muse, mutect2, varscan2
- F13A1 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161514, COSV53560791; called by muse, mutect2, varscan2
- FAAP24 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54280597; called by muse, mutect2, varscan2
- FAM124B | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | catalogued as COSV66272581; called by muse, mutect2, varscan2
- FAM171A1 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65317027; called by muse, mutect2, varscan2
- FAT3 | c.5623G>A p.D1875N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.325); catalogued as COSV53127603; called by muse, mutect2, varscan2
- FAT4 | c.5533G>T p.V1845L | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.673); catalogued as COSV58691310, COSV58700791; called by muse, mutect2, varscan2
- FATE1 | c.265A>T p.R89* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV64849047; called by muse, mutect2, varscan2
- FBN2 | c.1537A>T p.T513S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV52496714; called by muse, mutect2, varscan2
- FBXO40 | c.1138A>T p.T380S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57524928; called by muse, mutect2, varscan2
- FGF5 | c.723C>G p.S241R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.015); catalogued as COSV56890586; called by muse, mutect2, varscan2
- FHOD3 | c.3458C>A p.S1153* (on ENST00000359247 / NM_001281739.3; = p.S1170* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV57176969; called by muse, mutect2, varscan2
- FLVCR2 | c.1464G>C p.K488N | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV53162934; called by muse, mutect2, varscan2
- FNDC1 | c.2791T>A p.S931T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV51940473; called by muse, mutect2, varscan2
- FRZB | c.479-2A>T p.X160_splice | Splice Site (SNP) | VAF 11/61 reads (18%) | catalogued as COSV54554602; called by muse, mutect2, varscan2
- GABBR2 | c.1124C>A p.T375K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV52308181; called by muse, mutect2, varscan2
- GDF5 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65501945; called by muse, mutect2
- GFI1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.084); catalogued as rs776025480, COSV54043001; called by muse, mutect2, varscan2
- GLI1 | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.691); catalogued as rs267603605, COSV57363662; called by muse, mutect2, varscan2
- GLP2R | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52326159; called by muse, mutect2, varscan2
- GNA13 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.17); catalogued as COSV71474582, COSV71474880; called by muse, mutect2, varscan2
- GRID2 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV56220748; called by muse, mutect2, varscan2
- GRID2 | c.2083G>T p.G695* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV56178049, COSV56220754; called by muse, mutect2, varscan2
- GRK5 | c.1423A>T p.K475* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV64866728; called by muse, mutect2, varscan2
- GRM7 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100736078; called by muse, mutect2
- GRM7 | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV63148841; called by muse, mutect2, varscan2
- GYS2 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV53924634; called by muse, mutect2, varscan2
- H3C12 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV58152941; called by muse, mutect2, varscan2
- HBD | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV53082946, COSV53083332; called by muse, mutect2, varscan2
- HCST | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 56/390 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV52887938; called by muse, mutect2, varscan2
- HERC2 | c.3766G>T p.D1256Y | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55329569, COSV55343146; called by muse, mutect2, varscan2
- IARS2 | c.2059A>G p.K687E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.243); catalogued as COSV56960725; called by muse, mutect2
- IGHV3-20 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782671152; called by muse, mutect2, varscan2
- IL18RAP | c.895del p.E299Kfs*14 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as COSV51825347; called by mutect2, varscan2
- IMMT | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54480837; called by muse, mutect2, varscan2
- ITGA11 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59878749; called by muse, mutect2
- ITGA8 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65230549; called by muse, mutect2, varscan2
- ITGAX | c.2446G>T p.G816* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV51647027, COSV51651894; called by muse, mutect2, varscan2
- ITPR1 | c.4798A>C p.I1600L (on ENST00000354582; = p.I1585L on NM_002222.7) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV56986846; called by muse, mutect2, varscan2
- KCNK9 | c.157A>G p.N53D | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV57283067; called by muse, mutect2, varscan2
- KCNT2 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54086765, COSV54100416; called by muse, mutect2, varscan2
- KDM6B | c.2484del p.P829Lfs*65 | Frame Shift Del (DEL) | VAF 27/153 reads (18%) | catalogued as COSV54679083; called by mutect2, pindel, varscan2
- KMT2D | c.5837G>C p.G1946A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV56453057; called by muse, mutect2, varscan2
- KNDC1 | c.3977G>T p.W1326L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58839924; called by muse, mutect2
- KPNB1 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51597852; called by muse, mutect2
- KRTAP8-1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.983); catalogued as COSV61598105; called by muse, mutect2, varscan2
- LCE3E | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV64231901; called by muse, mutect2, varscan2
- LRP1B | c.10760G>T p.C3587F | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67236080; called by muse, varscan2
- LRRC15 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV61649919; called by muse, mutect2, varscan2
- LRRC6 | c.786G>T p.L262F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV51543455; called by muse, mutect2, varscan2
- LRRN2 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV65784108; called by muse, mutect2, varscan2
- LSP1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV61135286; called by muse, mutect2, varscan2
- LTBP2 | c.830+1G>T p.X277_splice | Splice Site (SNP) | VAF 12/66 reads (18%) | catalogued as COSV56209738; called by muse, mutect2, varscan2
- LYPLAL1 | c.406A>T p.R136* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV65106842; called by mutect2, varscan2
- MARK1 | c.1630G>T p.V544F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65068372; called by muse, mutect2, varscan2
- MAT1A | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64746039; called by muse, mutect2, varscan2
- MCF2L2 | c.1501A>T p.K501* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV61055553; called by muse, mutect2, varscan2
- MMD | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV50435153; called by muse, mutect2
- MMP16 | c.1591G>T p.G531C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54171236; called by muse, mutect2, varscan2
- MMP20 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV52776296; called by muse, mutect2, varscan2
- MMRN1 | c.2391C>G p.N797K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs981596032, COSV53338753; called by mutect2, varscan2
- MRC2 | c.2034A>T p.K678N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57640880; called by muse, mutect2, varscan2
- MTMR6 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67808682; called by mutect2, varscan2
- MUC16 | c.31696G>C p.E10566Q | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.14); catalogued as COSV67474289; called by muse, mutect2, varscan2
- MUC16 | c.29537C>G p.T9846S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); catalogued as COSV67474293; called by muse, mutect2, varscan2
- MUC5AC | c.927C>A p.H309Q | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.25); catalogued as COSV62254324; called by muse, mutect2, varscan2
- MUC5B | c.12962C>A p.T4321N | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.267); catalogued as COSV71593115; called by muse, mutect2, varscan2
- MYH1 | c.2248C>A p.L750M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99875467; called by muse, mutect2, varscan2
- MYH2 | c.4684G>T p.G1562* | Nonsense Mutation (SNP) | VAF 15/100 reads (15%) | catalogued as COSV55440845; called by muse, mutect2, varscan2
- MYO1C | c.586A>T p.S196C (on ENST00000648651 / NM_001080779.2; = p.S161C on NM_033375.5) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62999542; called by muse, mutect2, varscan2
- MYOCD | c.863G>C p.R288P | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58505663; called by muse, mutect2, varscan2
- MYT1 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV60507617; called by muse, mutect2, varscan2
- NAA16 | c.153G>C p.M51I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65065520; called by muse, mutect2, varscan2
- NELL2 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61577497; called by muse, mutect2, varscan2
- NOL6 | c.1779G>T p.Q593H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53042866; called by muse, mutect2, varscan2
- NPAP1 | c.2910T>G p.S970R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as COSV61508148; called by muse, mutect2, varscan2
- NPHS2 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV62635747; called by muse, mutect2
- NRXN1 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV100454322; called by muse, mutect2
- NSRP1 | c.897T>G p.S299R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV55934240; called by muse, mutect2, varscan2
- NUDCD1 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53457805; called by muse, mutect2, varscan2
- NUFIP2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV56604041; called by muse, mutect2
- OCA2 | c.1823_1824insA p.Q609Pfs*8 | Frame Shift Ins (INS) | VAF 17/142 reads (12%) | catalogued as COSV100667355; called by mutect2, pindel, varscan2
- OCA2 | c.1594T>A p.W532R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV62348883; called by muse, mutect2, varscan2
- OMD | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65020284; called by muse, mutect2, varscan2
- OR11H4 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59560447; called by muse, mutect2, varscan2
- OR2M5 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 107/393 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV63546498; called by muse, mutect2, varscan2
- OR2T34 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV60899605, COSV60900803; called by muse, mutect2, varscan2
- OR4C3 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV60587131; called by muse, mutect2, varscan2
- OR4P4 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV58922531; called by muse, mutect2, varscan2
- OR51D1 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62914311, COSV62914347; called by muse, mutect2
- OR51L1 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); catalogued as rs150980273; called by muse, mutect2, varscan2
- OR5L1 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61734348; called by muse, mutect2, varscan2
- OR5M3 | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs973923348, COSV56567255; called by muse, mutect2, varscan2
- OR6F1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57468272, COSV57469037; called by muse, mutect2, varscan2
- OR8B8 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV60144900; called by muse, mutect2
- OVCH1 | c.2842G>A p.G948S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs745853862, COSV58964568; called by muse, varscan2
- PACSIN3 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066424; called by muse, mutect2, varscan2
- PASD1 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV64854226, COSV64855802; called by muse, mutect2, varscan2
- PASD1 | c.1872C>G p.F624L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV64855806; called by muse, mutect2, varscan2
- PAX2 | c.998T>A p.M333K (on ENST00000428433 / NM_003987.5; = p.M310K on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV62291582; called by muse, mutect2, varscan2
- PAX4 | c.471T>A p.S157R | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV58387547, COSV58389431; called by muse, mutect2
- PAX7 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV64750877; called by muse, mutect2, varscan2
- PCDH10 | c.1759C>A p.R587S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.095); catalogued as COSV52088168, COSV52103034; called by muse, mutect2, varscan2
- PCDH11X | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.927); catalogued as COSV53476362; called by muse, mutect2, varscan2
- PCDH15 | c.2869-1G>A p.X957_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100227223, COSV57332878; called by muse, mutect2, varscan2
- PCDHB16 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV53364278, COSV53372418; called by muse, mutect2, varscan2
- PCDHB7 | c.1978G>C p.V660L | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.33); catalogued as COSV50772567, COSV50778733; called by muse, mutect2, varscan2
- PCNX2 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV50814344; called by muse, mutect2, varscan2
- PDGFRA | c.3096G>T p.E1032D | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57269695; called by muse, mutect2, varscan2
- PDSS2 | c.927G>C p.M309I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV64655629; called by muse, mutect2, varscan2
- PEG3 | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV55637266; called by muse, mutect2, varscan2
- PEX12 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56778315; called by muse, mutect2, varscan2
- PID1 | c.144G>T p.M48I (on ENST00000354069 / NM_001330156.1; = p.M46I on NM_017933.5) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.885); catalogued as COSV62477267; called by muse, mutect2
- PKHD1 | c.6972C>G p.I2324M | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61881760; called by muse, mutect2, varscan2
- PLEKHH2 | c.4378C>T p.P1460S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV56756212; called by muse, mutect2, varscan2
- POLE | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV57683006; called by muse, mutect2, varscan2
- POLR2B | c.3346G>T p.V1116F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV55274114, COSV55274330; called by muse, mutect2, varscan2
- POT1 | c.1430G>C p.R477T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62930355, COSV62934021; called by muse, mutect2, varscan2
- POU3F1 | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100884675, COSV65948788; called by muse, mutect2, varscan2
- PPP1R7 | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV52145477; called by muse, mutect2, varscan2
- PPP2R2A | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV60097585; called by muse, mutect2, varscan2
- PRKG2 | c.462-2A>T p.X154_splice | Splice Site (SNP) | VAF 18/86 reads (21%) | catalogued as COSV52326354; called by muse, mutect2, varscan2
- PTK2 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as COSV61787476; called by muse, mutect2, varscan2
- PTPN9 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60724282; called by muse, mutect2, varscan2
- PTPRD | c.3589G>T p.D1197Y | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV61956710; called by muse, mutect2, varscan2
- RAB11FIP1 | c.372-2A>C p.X124_splice | Splice Site (SNP) | VAF 11/47 reads (23%) | catalogued as COSV54761114; called by muse, mutect2, varscan2
- RALGPS1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52224631; called by muse, mutect2, varscan2
- REST | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58361264, COSV58361801; called by muse, mutect2, varscan2
- RHBDD3 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV99328486; called by mutect2, varscan2
- RPS6KB1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV56677694; called by muse, mutect2
- RUFY2 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.962); catalogued as COSV61191497; called by muse, mutect2, varscan2
- RYR3 | c.11063C>A p.S3688Y (on ENST00000389232; = p.S3689Y on NM_001036.6) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV66795325; called by muse, mutect2, varscan2
- SAMD9L | c.160del p.D54Tfs*3 | Frame Shift Del (DEL) | VAF 13/106 reads (12%) | catalogued as COSV59083080; called by mutect2, pindel, varscan2
- SBK1 | c.679G>T p.G227W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59397453; called by muse, mutect2, varscan2
- SEMA6D | c.2255G>A p.G752E (on ENST00000316364 / NM_153618.2; = p.G690E on NM_020858.2) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV60379103; called by muse, mutect2, varscan2
- SERPINA6 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58585717; called by muse, mutect2, varscan2
- SERPINB3 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52192213; called by muse, mutect2, varscan2
- SERPINB8 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV54639938; called by muse, mutect2, varscan2
- SGCA | c.251A>T p.H84L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV56249713; called by muse, mutect2, varscan2
- SLC12A2 | c.3154T>A p.C1052S | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV52472668; called by muse, mutect2, varscan2
- SLC44A1 | c.761-1G>C p.X254_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV58265339; called by muse, mutect2, varscan2
- SLC5A4 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 24/128 reads (19%) | catalogued as COSV56671279, COSV56671556; called by muse, mutect2, varscan2
- SLC6A19 | c.767C>A p.T256K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs375879452, COSV58672096, COSV58675414; called by muse, varscan2
- SLC6A5 | c.2056C>G p.P686A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54228152; called by muse, mutect2
- SLC7A7 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV53537439; called by muse, mutect2, varscan2
- SPANXN3 | c.44G>C p.S15T | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV65140477; called by muse, mutect2, varscan2
- SPIRE1 | c.1356G>C p.K452N (on ENST00000409402 / NM_001128626.2; = p.K438N on NM_020148.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.234); catalogued as COSV59157949; called by muse, mutect2, varscan2
- SPOCK3 | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.341); catalogued as COSV62722389; called by muse, mutect2, varscan2
- SPTA1 | c.6897C>A p.C2299* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV63755124; called by muse, mutect2, varscan2
- SSX3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV53644495; called by muse, mutect2, varscan2
- STARD10 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV58325889; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3176C>T p.T1059I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV59132255; called by muse, mutect2, varscan2
- STOX1 | c.2363G>T p.R788M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); catalogued as COSV53815652; called by muse, mutect2, varscan2
- STYXL2 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372292395; called by muse, mutect2
- SYN3 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV60510415; called by muse, mutect2, varscan2
- SYNE3 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62080249, COSV62084242; called by muse, mutect2, varscan2
- TAF1L | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774366817, COSV54261717; called by muse, mutect2, varscan2
- TBC1D1 | c.2322G>T p.W774C | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790920; called by muse, mutect2, varscan2
- TBC1D1 | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 17/142 reads (12%) | catalogued as COSV99790924; called by muse, mutect2, varscan2
- TBC1D16 | c.1028A>T p.D343V | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV60478685; called by muse, mutect2
- TDRD5 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV54242966; called by muse, mutect2, varscan2
- TICRR | c.1177-1G>T p.X393_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV51542648; called by muse, mutect2
- TLL2 | c.1753C>A p.H585N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100780550, COSV63573287, COSV63575956; called by muse, mutect2, varscan2
- TLN2 | c.1645C>G p.Q549E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV60891090; called by muse, mutect2, varscan2
- TMEM132B | c.3073A>T p.K1025* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV54757343; called by muse, mutect2, varscan2
- TMEM168 | c.135G>T p.L45F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs752852979, COSV57181167; called by muse, mutect2, varscan2
- TMPRSS3 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52304286; called by muse, mutect2, varscan2
- TP53INP1 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV61331620, COSV61331826; called by muse, mutect2, varscan2
- TPX2 | c.2138A>G p.H713R | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778633428, COSV55920304; called by muse, mutect2, varscan2
- TRAM1L1 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV60292107, COSV60292308; called by muse, mutect2, varscan2
- TRIM29 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs767499147, COSV59280375, COSV59280957; called by muse, mutect2, varscan2
- TRIM69 | c.1499A>T p.Q500L (on ENST00000329464 / NM_182985.5; = p.Q341L on NM_080745.5) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV57804112; called by muse, mutect2, varscan2
- TTPA | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99478369, COSV99478463; called by muse, varscan2
- TUBA8 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV57813279; called by muse, mutect2, varscan2
- UGT2B7 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV59443915; called by muse, mutect2, varscan2
- USH2A | c.7657T>A p.W2553R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56386959; called by muse, mutect2
- USH2A | c.5399G>C p.W1800S | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149920, COSV56386971; called by muse, varscan2
- USH2A | c.5354C>G p.T1785R | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56386983; called by muse, varscan2
- USP32 | c.4753G>T p.D1585Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56270778; called by muse, mutect2, varscan2
- USP9X | c.5015G>T p.R1672M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61070852; called by muse, mutect2, varscan2
- USPL1 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV55000457; called by muse, mutect2, varscan2
- VIRMA | c.4792A>G p.T1598A | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52586517; called by muse, mutect2, varscan2
- WDR6 | c.1731C>G p.C577W | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.785); catalogued as COSV58245454; called by muse, mutect2
- WIPI1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV50930357; called by muse, mutect2, varscan2
- WWTR1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs763418690, COSV62291763; called by muse, mutect2, varscan2
- XIRP2 | c.3602A>T p.Q1201L (on ENST00000628543; = p.Q1376L on NM_152381.6) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54709516; called by muse, mutect2, varscan2
- YIPF1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50777696; called by muse, mutect2
- ZC3HAV1 | c.2018C>A p.S673Y | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV54297140; called by muse, mutect2
- ZC3HAV1 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV54297154; called by muse, mutect2
- ZFPM2 | c.2190G>C p.Q730H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV65874291; called by muse, mutect2, varscan2
- ZNF479 | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58639794; called by muse, mutect2, varscan2
- ATR | c.6898-3del | Splice Region (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- CCL14 | c.236G>T p.S79I (on ENST00000618404 / NM_032963.4; = p.S95I on NM_032962.4) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- DYNC1H1 | c.9124_9126dup p.L3042dup | In Frame Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel
- FAT1 | c.12598del p.V4200Ffs*6 | Frame Shift Del (DEL) | VAF 15/128 reads (12%) | called by mutect2, varscan2
- HEATR9 | c.252C>A p.H84Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- INSRR | c.2239del p.A747Qfs*28 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- LINC01559 | n.400G>T | Splice Region (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- PPRC1 | c.1219del p.L407Sfs*10 | Frame Shift Del (DEL) | VAF 28/184 reads (15%) | called by mutect2, pindel, varscan2
- RAB6D | c.555A>C p.R185S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS4Y2 | c.272_274del p.S91del | In Frame Del (DEL) | VAF 4/17 reads (24%) | called by mutect2, varscan2
- SPR | c.402del p.T135Lfs*5 | Frame Shift Del (DEL) | VAF 18/149 reads (12%) | called by mutect2, pindel, varscan2
- TPTE | c.1136G>C p.S379T (on ENST00000618007 / NM_199261.4; = p.S361T on NM_199259.4) | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); called by muse, mutect2
- ABCG1 | c.894G>T p.R298= | Silent (SNP) | VAF 29/244 reads (12%) | catalogued as COSV59206032; called by muse, mutect2, varscan2
- ADGRG4 | c.6919C>A p.R2307= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs376547734, COSV54959019; called by muse, mutect2, varscan2
- ANKRD26 | c.1266T>C p.S422= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV65795301; called by muse, mutect2, varscan2
- ANO6 | c.1290G>A p.V430= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs1308184708, COSV57662771; called by muse, mutect2, varscan2
- APMAP | c.180G>T p.L60= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV54174675; called by muse, mutect2, varscan2
- ATP11C | c.2982A>G p.G994= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1297443682, COSV59566722; called by muse, mutect2, varscan2
- ATP8B2 | c.3243C>T p.P1081= (on ENST00000672630; = p.P1048= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as COSV59246625; called by muse, mutect2, varscan2
- BRINP2 | c.2268G>T p.V756= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV64178207; called by muse, mutect2
- C1orf226 | c.444G>A p.L148= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV63395721; called by muse, mutect2, varscan2
- CASP4 | c.198T>C p.R66= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs1260480052, COSV67744533; called by muse, mutect2, varscan2
- CD1E | c.693T>C p.H231= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as rs1226448121, COSV63771412; called by muse, mutect2, varscan2
- CELSR2 | c.6909G>A p.T2303= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs150014940; called by muse, mutect2, varscan2
- CGNL1 | c.1047A>G p.S349= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1360349045, COSV55569983; called by muse, mutect2, varscan2
- CNGA4 | c.981T>A p.P327= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV66006266; called by muse, mutect2
- CNTNAP2 | c.492G>T p.L164= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV62201645; called by muse, mutect2, varscan2
- COL16A1 | c.570C>A p.S190= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV54708393; called by muse, mutect2
- CTSC | c.1092G>A p.L364= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV57058536; called by muse, mutect2, varscan2
- CYYR1 | c.30A>T p.P10= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV54833623; called by muse, mutect2, varscan2
- DMRTA2 | c.942G>A p.R314= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV68672736; called by muse, mutect2, varscan2
- DNAI2 | c.969G>A p.L323= | Silent (SNP) | VAF 56/207 reads (27%) | catalogued as COSV56759550; called by muse, mutect2, varscan2
- DPEP2 | c.1431C>A p.A477= | Silent (SNP) | VAF 47/239 reads (20%) | catalogued as COSV52054913; called by muse, mutect2, varscan2
- ERBB2 | c.291G>A p.Q97= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV54073487, COSV54085494; called by muse, mutect2, varscan2
- FAM107A | c.102G>T p.L34= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV62980782; called by muse, mutect2, varscan2
- FAM163A | c.120C>A p.T40= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV59203667, COSV59204251; called by muse, mutect2
- FMN2 | c.2388C>A p.V796= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV60435299; called by muse, mutect2, varscan2
- GALNT7 | c.1104C>T p.T368= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1332696812, COSV53931379; called by muse, mutect2, varscan2
- GFRA3 | c.684G>T p.G228= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV51229096, COSV99218344; called by muse, mutect2, varscan2
- GFRAL | c.744G>A p.V248= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs748931694, COSV61232059; called by muse, mutect2, varscan2
- GHDC | c.723G>A p.R241= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as COSV56988516; called by muse, mutect2, varscan2
- GLI2 | c.759C>G p.P253= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV58044478; called by muse, mutect2, varscan2
- GPC6 | c.378G>T p.R126= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV65515967; called by muse, mutect2, varscan2
- GPR12 | c.436C>T p.L146= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV67344476; called by muse, mutect2, varscan2
- GPR61 | c.867C>A p.L289= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV63983960; called by muse, mutect2, varscan2
- GPRASP2 | c.2355G>A p.Q785= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV59991699; called by muse, mutect2
- GSN | c.123G>A p.Q41= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100376030; called by muse, varscan2
- H2BW1 | c.468C>T p.S156= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs370071971, COSV54220528; called by muse, mutect2, varscan2
- HOXA5 | c.480G>A p.A160= | Silent (SNP) | VAF 31/201 reads (15%) | catalogued as rs202017218, COSV56073789; called by muse, mutect2, varscan2
- HPS4 | c.870A>T p.T290= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV61103980; called by muse, mutect2
- HYDIN | c.14979C>A p.P4993= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV66639727; called by muse, mutect2, varscan2
- IL7R | c.1248C>G p.P416= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100286448, COSV57409599; called by muse, mutect2, varscan2
- IL9R | c.441G>C p.L147= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV99729573; called by muse, mutect2
- ITGAD | c.1779C>A p.L593= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV66758485; called by muse, mutect2
- ITGAD | c.2595C>A p.P865= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV66758486; called by muse, mutect2, varscan2
- KCNA6 | c.1038G>T p.L346= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs757378869, COSV54976019; called by muse, mutect2, varscan2
- KRBA1 | c.672G>T p.R224= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV55442140; called by muse, mutect2, varscan2
- LPL | c.1209C>G p.L403= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV60931517; called by muse, mutect2, varscan2
- LRRC24 | c.1440C>T p.F480= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs973747412, COSV99467381; called by muse, mutect2
- LRRC8C | c.1735C>T p.L579= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV64998934; called by muse, mutect2, varscan2
- LTB4R2 | c.486G>T p.R162= (on ENST00000528054; = p.R131= on NM_019839.5) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99350610; called by muse, varscan2
- MATN1 | c.201C>A p.V67= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV65650868; called by muse, mutect2, varscan2
- MS4A6E | c.30C>G p.T10= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV55727249; called by muse, mutect2, varscan2
- MUC16 | c.11475A>C p.P3825= | Silent (SNP) | VAF 28/180 reads (16%) | catalogued as COSV101202441, COSV67474302; called by muse, mutect2, varscan2
- MYH1 | c.2247C>A p.L749= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV56850622, COSV99875468; called by muse, mutect2, varscan2
- MYH6 | c.5313G>A p.L1771= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as COSV59306383; called by muse, mutect2, varscan2
- NALCN | c.2109C>T p.I703= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs1019776644, COSV51943405; called by muse, mutect2, varscan2
- NIBAN3 | c.1959T>C p.S653= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV53109837; called by muse, mutect2, varscan2
- NLRP2 | c.2955C>T p.V985= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV54756469; called by muse, mutect2, varscan2
- NOTCH4 | c.1842C>A p.L614= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV66681582; called by muse, mutect2, varscan2
- NYAP2 | c.1158C>T p.H386= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV56008423; called by muse, mutect2
- OR10X1 | c.903C>T p.I301= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV63767237, COSV63767322; called by muse, mutect2, varscan2
- OR6V1 | c.168C>G p.P56= | Silent (SNP) | VAF 32/227 reads (14%) | catalogued as COSV69237394; called by muse, mutect2, varscan2
- OSBPL10 | c.675A>T p.A225= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV67340627; called by muse, mutect2, varscan2
- PKHD1L1 | c.435C>T p.T145= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV65745649; called by muse, mutect2, varscan2
- PKHD1L1 | c.8304G>T p.G2768= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV65743060, COSV65745659; called by muse, mutect2, varscan2
- PKNOX1 | c.813G>T p.T271= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV52336977; called by muse, mutect2, varscan2
- PRMT1 | c.702G>A p.E234= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV67159810; called by muse, mutect2, varscan2
- PTPRC | c.408C>T p.L136= | Silent (SNP) | VAF 21/283 reads (7%) | catalogued as rs1239293392, COSV61414078; called by muse, mutect2
- PTPRZ1 | c.288T>C p.H96= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV66439364; called by muse, mutect2, varscan2
- RSBN1 | c.1701C>T p.T567= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs960914700, COSV54733109; called by muse, mutect2, varscan2
- SALL2 | c.972C>T p.T324= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1181391004, COSV58103963; called by muse, mutect2, varscan2
- SCD5 | c.351C>T p.S117= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as rs936938166, COSV51103065; called by muse, mutect2
- SERTAD2 | c.258C>T p.F86= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1261100399, COSV57640538; called by muse, mutect2, varscan2
- SH3BP5L | c.657C>T p.I219= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs759676523, COSV63539441; called by muse, mutect2, varscan2
- SLAIN2 | c.846C>G p.A282= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV51907521; called by muse, mutect2, varscan2
- SLC5A1 | c.1077T>A p.V359= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV56686288; called by muse, mutect2, varscan2
- SLC6A15 | c.549T>A p.P183= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV57022416, COSV57025231; called by muse, mutect2, varscan2
- SLC6A5 | c.507G>T p.V169= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV54228143; called by muse, mutect2, varscan2
- SMARCAD1 | c.1821G>T p.A607= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs111425618, COSV62774135, COSV62774909; called by muse, mutect2, varscan2
- SYDE2 | c.1467T>C p.N489= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV52316092; called by muse, mutect2, varscan2
- SYPL2 | c.267C>A p.I89= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100881562, COSV63995040; called by muse, mutect2
- TAS2R16 | c.690C>T p.A230= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs187186713, COSV50797402, COSV50799191; called by muse, mutect2, varscan2
- TFDP3 | c.1149A>G p.P383= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV59537450; called by muse, mutect2
- THADA | c.1341G>A p.L447= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV57686145; called by muse, mutect2
- TTN | c.23082A>G p.S7694= (on ENST00000591111; = p.S6767= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as COSV60137327; called by muse, mutect2, varscan2
- VAC14 | c.1626G>A p.R542= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV55754310; called by muse, mutect2
- WDR89 | c.813A>G p.E271= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV50827001; called by muse, mutect2, varscan2
- XIRP2 | c.8436G>A p.L2812= (on ENST00000628543; = p.L2987= on NM_152381.6) | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as COSV54709527, COSV99747742; called by muse, mutect2
- ZNF536 | c.2151C>A p.P717= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV62826482; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302055 C>G | 5'Flank (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472260 G>T | 3'Flank (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- TMBIM6 | c.-31+550G>C | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as COSV57278519, COSV99920664; called by muse, mutect2, varscan2
- TNN | c.-74G>T | 5'UTR (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99511619; called by muse, mutect2, varscan2
